TARGET case TARGET-30-PAKHPN — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/3e5ca872-d9e6-5bec-8fea-9efeb3e0f801

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.1 years (1,488 days); Year of diagnosis: 2000; Days to last follow up: 1,569 days (4.3 years); INSS stage: Stage 4.
